CCDI case PBCNSR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/90c0a162-fc5e-4c7d-bbc0-7d8ee878b27b

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Papillary carcinoma, NOS: ICD-O-3 morphology code: 8050/3; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 15.6 years (5,703 days).

Biospecimens (3 samples)
- Sample 0DW8GK: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DW8H3, 0DW8HD (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
